Somatic mutation profile of tumor specimen 0DLRHS from CCDI case PBBYTG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 23.6 years (8,625 days).
Specimen 0DLRHS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb85349e-bdff-4a06-aecd-5abfcd81686e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLRHI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03b14ac6-cb2d-45c9-a8e4-800faec68dd4

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Splice Site 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.4600C>T p.R1534* (on ENST00000358273 / NM_001042492.3; = p.R1513* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 274/373 reads (73%) | catalogued as rs760703505, CM941093, COSV62191852; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DNAJC10 | c.1807C>T p.R603W | Missense Mutation (SNP) | VAF 87/944 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769744719, COSV51148716; called by muse, mutect2
- DNM1L | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 35/941 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs918224990, COSV56776970; called by muse, mutect2
- EGFR | c.1934C>G p.S645C | Missense Mutation (SNP) | VAF 54/1016 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as rs772046081, COSV51772147; called by muse, mutect2
- GIPC3 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 128/298 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.845); catalogued as COSV59258602, COSV59259831; called by muse, mutect2, varscan2
- GPBP1L1 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 20/600 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as COSV51970767; called by muse, mutect2
- ILDR2 | c.704-2A>G p.X235_splice | Splice Site (SNP) | VAF 64/561 reads (11%) | catalogued as rs780189949; called by muse, mutect2, varscan2
- JMJD8 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 42/415 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as rs199605055; called by muse, mutect2, varscan2
- PTPRO | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 457/743 reads (62%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.026); catalogued as rs147697088; called by muse, varscan2
- TBC1D9B | c.2428C>T p.P810S | Missense Mutation (SNP) | VAF 293/806 reads (36%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs777112854; called by muse, mutect2, varscan2
- CIP2A | c.818G>A p.R273K | Missense Mutation (SNP) | VAF 256/692 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MED1 | c.548A>T p.D183V | Missense Mutation (SNP) | VAF 82/1526 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDGFRA | c.2154G>A p.R718= | Splice Region (SNP) | VAF 740/961 reads (77%) | called by muse, mutect2, varscan2
- MAPK8IP1 | c.1272G>A p.E424= | Silent (SNP) | VAF 188/303 reads (62%) | called by muse, mutect2, varscan2
- SORCS2 | c.2628C>T p.L876= | Silent (SNP) | VAF 590/753 reads (78%) | catalogued as rs768917104; called by muse, mutect2, varscan2
